Somatic mutation profile of tumor specimen MP2PRT-PAVTFG-TMP1-A (aliquot MP2PRT-PAVTFG-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVTFG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,327 days).
Specimen MP2PRT-PAVTFG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaf00649-874c-4aa0-8c86-0663fb5bd647.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTFG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTFG-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b3a35a4-bec8-4a65-8705-1b89e6f44beb

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 130/423 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as rs1169875049; called by muse, mutect2
- GDF9 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.865); catalogued as COSV99737553; called by muse, mutect2, varscan2
- OR4Q2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 22/628 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1164371594; called by muse, mutect2
- PPFIA2 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 130/396 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs756811275, COSV61044575, COSV61052417; called by muse, mutect2, varscan2
- SHROOM2 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 257/647 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs775101774, COSV66608740; called by muse, mutect2, varscan2
- THBS1 | c.2959G>A p.V987I | Missense Mutation (SNP) | VAF 123/358 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs778612797, COSV99527749; called by muse, mutect2, varscan2
- VWA3A | c.2387C>T p.A796V | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763508884; called by muse, mutect2
- CABLES1 | c.350_359del p.G117Afs*13 | Frame Shift Del (DEL) | VAF 139/1066 reads (13%) | called by mutect2, pindel*
- MAGEB10 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- PLEKHM2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 25/482 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- APC2 | c.1038C>T p.R346= | Silent (SNP) | VAF 35/748 reads (5%) | catalogued as rs1568169465; called by muse, mutect2
- COL6A1 | c.2997C>T p.G999= | Silent (SNP) | VAF 62/1544 reads (4%) | catalogued as rs780912204, COSV62612834; called by muse, mutect2
- CT47B1 | c.747G>A p.P249= | Silent (SNP) | VAF 154/363 reads (42%) | catalogued as rs745694817, COSV64890965; called by muse, mutect2, varscan2
- PLXNA1 | c.2787C>T p.S929= | Silent (SNP) | VAF 167/456 reads (37%) | catalogued as rs778324443, COSV52526787, COSV52529027; called by muse, mutect2, varscan2
- ZNF202 | c.1737G>A p.A579= | Silent (SNP) | VAF 177/520 reads (34%) | catalogued as rs760478791; called by muse, mutect2, varscan2
